Surgical pathology report (de-identified scan), TCGA case TCGA-66-2795, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2795-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Mediastinal squamous epithelium

Clinical diagnosis and question

Bronchial carcinoma left upper lobe, attempted angioplasty upper lobe, discontinuation with central tumor in

REPORT ON FINDINGS**Macroscopy**

1.) Mediastinal squamous epithelium: 0.6 cm hard pale brownish specimen. Inflated, fixed left lung measuring 17 x 12 cm at the base and up to 27 cm high, central bronchus resection plane located 3 cm proximal to the bifurcation of the upper lobe bronchus. A staple suture line runs from the hilus in a ventrocaudal direction over the upper and lower lobes for 7.5 cm in each case and dorsal over S2 and 6 for 6.5 cm in each case, evidently corresponding staple suture lines. Main bronchus largely skeletonized. At the hilus four partly lesioned, mobile blackish nodes between 0.4 and 0.8 cm. Resection margin of pulmonary artery shows high-grade lesion. Apical and lateral region over S1, 2 and 3 shows a 16 x 14.5 cm area of parietal pleura that shows predominantly extensive adhesion and marginally loose attachment in parts. Ostium of upper lobe bronchus constricted by a central moderately firm, pale brown to whitish tumor, max. 4.9 cm in size, in the upper lobe, with a predominantly relatively clear and arcuate demarcation and patchy grayish-black pigmentation in parts. Extension of tumor right up to hilar resection surface, where 1.5 cm is questionably part of the pericardial sac, which is not macroscopically infiltrated. Involvement of some grayish-black nodes up to 1.5 cm in size by the tumor. Narrowing of numerous blood vessels and questionable wall infiltration of an already patent pulmonary artery branch of the upper lobe, with not tumor tissue discernible in the lumen. In S3 at the junction with S3 laterally below the section of parietal pleura is a 3.5 cm hemorrhagic zone, partly with a clear demarcation, extending to the pleura. Peripheral bronchi of the upper lobe in parts slightly dilated and filled with thick mucus, rest of parenchyma of the upper and lower lobes inconspicuous. From the bifurcation of the bronchus into the basal lower lobe bronchi, three blackish nodes between 0.4 and 0.7 cm. In the subpleural region in S6 at the junction with S8 a 0.3 cm flat blackish node.

3.) Repeat resection material from pulmonary artery: irregular portion of pulmonary artery measuring 3.7 x max 1.3 cm

4.) Interlobar LN (station 11): 0.7 cm lesioned node

5.) Pulmonary ligament LN (station 9): 0.6 cm node with surrounding tissue.

6.) Paraesophageal LN (station 8): 0.6 cm node with surrounding tissue.

7.) Paraaortic LN (station 6): two lesioned grayish-black nodes or node parts, 0.8 and 0.4 cm.

8.) Low paratracheal LN (station 4) left: 1 cm node with surrounding tissue.

9.) Low paratracheal LN (station 4) right: 0.4 cm node.

[page 2 of 2]
Examined:

Re 1.) Rapid section remains,

Re 2.) a: Tumor with rest of parenchyma, b: tumor with ostium of upper lobe bronchus and involved nodes as well as central blood vessels, c: tumor with pulmonary artery upper lobe branch, d: tumor with hilar resection surface (color-marked), e: tumor with questionable portion of pericardial sac (resection margin color-marked), f: hemorrhagic zone, g: pleural adhesion zone in S1, h: central bronchus resection plane and resection margin pulmonary artery, i: mobile hilar nodes and resection margin pulmonary veins, j: node subpleural and at the bronchus bifurcation of the lower lobe,

Re 3.)-9.) All material (in 3. preparation lamellated),

16 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Re 1.) Immediate intraoperative evaluation (): squamous cell carcinoma.

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Locally advanced, central, bronchopulmonary, histologically poorly differentiated, large-cell and polymorphocellular, nonkeratinizing squamous cell carcinoma of the left upper lobe of the lung (G3). Tumor classification according to this picture pT4 pN1 V1 RX(R1?), stage IIIB. C34.M8070/3.

Secondary diagnosis/diagnoses:

Tumor necroses. Active resorptive alveolar and lymphofollicular interstitial inflammation in the lung parenchyma adjacent to the tumor. Lung tissue necrosis with marginal organizing and fibrous remodeling process under the pleural adhesion area in S1. Fresh hemorrhagic pulmonary infarction in the boundary region of S1/S3. Fibrinous pleuritis and pleural adhesions. Moderate anthracotic pigment deposits in the lung parenchyma and varying degrees of partly mixed dust pigment deposits in the lymph nodes with reactive accumulation of macrophages.

Remark/addendum:

The carcinoma shows partially endobronchial growth as far as the ostium of the upper lobe, continuously metastasized to local bronchopulmonary lymph nodes with invasion via the mediastinal pleura into the mediastinum, where it reaches the resection plane in places. This finding explains the pT4 classification, although the evidently co-resected layer of parietal pericardium is not reached or infiltrated by the tumor. The precondition is thus also met for the R1 category. If this area is directly followed by the preparation registered under 1.), which is likewise marginally occupied by tumor, a category of R0 may also be diagnosed. Large pulmonary vessels are only surrounded, but not invaded by tumor. The resection margins of the main bronchus, the large pulmonary vessels, the lower lobe of the lung and all other lymph nodes are tumor-free.

Source: NCI Genomic Data Commons file 4fbe716c-f15b-451c-9e6b-2f6cdb4c3f82 (TCGA-66-2795.7993DE3E-AFEB-4EAF-96FA-4EFBB5167130.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).